Somatic mutation profile of tumor specimen TCGA-13-0794-01A (aliquot TCGA-13-0794-01A-01W-0371-08) from TCGA case TCGA-13-0794, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.1 years (21,945 days).
Specimen TCGA-13-0794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 881fddf0-4fec-49d5-9064-99fc34b3d591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0794-10A (Blood Derived Normal), aliquot TCGA-13-0794-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/186f404a-5762-4215-9a66-516d2beb3ec0

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNKSR2 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99667915; called by muse, varscan2
- DPYS | c.331A>T p.I111F | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV100679430; called by muse, mutect2, varscan2
- IRF4 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV101110808; called by muse, varscan2
- LCMT2 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as COSV99979857, COSV99979990; called by muse, varscan2
- MAPK10 | c.1151A>G p.Q384R (on ENST00000359221 / NM_001351625.2; = p.Q422R on NM_002753.5) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100174073; called by muse, varscan2
- MGAM | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 108/514 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72073879, COSV72075314; called by muse, varscan2
- PRUNE2 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs370383759; called by muse, varscan2
- TLN1 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 211/972 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100147513, COSV59209565; called by muse, varscan2
- TROAP | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.07); catalogued as COSV99226732; called by muse, varscan2
- XRN2 | c.2747G>T p.G916V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as COSV101018160; called by muse, varscan2
- AKR1C4 | c.486C>A p.S162= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as COSV99578586; called by muse, mutect2, varscan2
